Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GP, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GP-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

A) SIGMOID COLON:

MALIGNANT EPITHELIOID NEOPLASM (6 cm) INVOLVING SUBMUCOSA AND MUSCULARIS PROPRIA,
CONSISTENT WITH METASTATIC MELANOMA.

(see comment)

Mesocolic margin free of tumor.

ICD-0-3

Melanoma, epithelioid 87713

Site ^{C&F} large intestine 018.9

rect sigmoid colon 018.7

Sp 11/27/13

B) PROXIMAL MARGIN:

Bowel wall and mucosa, no melanoma identified.

C) DISTAL MARGIN:

Bowel wall and mucosa, no melanoma identified.

COMMENT

There is an area of this case apparently diffusely colonized by microorganisms. These will be further characterized and an addendum issued.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) SIGMOID COLON - A 20 cm long and 3.5 cm in diameter section of colon with attached fat, 4.0 cm in maximum dimension. There is a polypoid fungating tan mass in the mucosa (6.0 x 4.0 x 2.5 cm) infiltrating the entire thickness of the colon and extending to the serosa. The mass is located 3 cm from one stapled margin and 6 cm from the other. The mass is located at least 4 cm from the mesocolic resection margin. The adjacent mucosa is unremarkable.

INK CODE: Blue - mesocolic margin; orange - serosal surface.

SECTION CODE: A1, mesocolic margin en face; A2, colonic margin (3 cm from mass), en face; A3, colonic margin (6 cm from mass), en face; A4, A5, representative sections of tumor; A6, random colon. Majority of the tumor and non-neoplastic colon was submitted to the Tumor Bank.

(B) PROXIMAL MARGIN - A circular mucosal tissue 6.0 cm in maximum circumference and 0.4 cm in length. Bisected and entirely submitted in B.

(C) DISTAL MARGIN - A circular mucosal tissue 6.0 cm in maximum circumference and 1.2 cm in length. Bisected and entirely submitted in C.

CLINICAL HISTORY

Metastatic melanoma, sigmoid colon.

SNOMED CODES

T-59300, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

These tests have not been

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

Addendum completed by

COMMENT

A representative slide (A5) was presented to (microbiology section) and his opinion is as follows:

A large area of bacterial colonization by cocci and filamentous bacilli (? Actinomycete) in the middle of tumor necrosis is evident. The area of bacterial overgrowth is at the (? mucosa) surface of the tumor mass and the significance is uncertain given that the tumor has been resected. Additional studies for these organisms are likely unnecessary.

Released by:

-----END OF REPORT-----

Criteria	lw 10/28/13	Yes	No
HIP/AA Discrepancy			✓

Source: NCI Genomic Data Commons file d867dcb5-62ec-45de-8c1e-a2e31aab99ec (TCGA-D3-A8GP.C4123D5F-FAC1-4FCF-96B5-9D8B9090371D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).